Somatic mutation profile of tumor specimen TCGA-A2-A0T7-01A (aliquot TCGA-A2-A0T7-01A-21D-A099-09) from TCGA case TCGA-A2-A0T7, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 51.4 years (18,756 days).
Specimen TCGA-A2-A0T7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f838b6c4-5ca0-4620-88ac-7b85bb067a69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0T7-10A (Blood Derived Normal), aliquot TCGA-A2-A0T7-10A-01D-A099-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96351cff-87bc-475f-9a34-cc11fd4c36ab

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Nonsense Mutation 2, Intron 2, Frame Shift Del 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.9139C>T p.R3047* | Nonsense Mutation (SNP) | VAF 63/156 reads (40%) | catalogued as rs121434219, CM960114, COSV53724126; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 21/125 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3129G>A p.M1043I | Missense Mutation (SNP) | VAF 12/52 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs121913283, CM126698, COSV55873376, COSV55878974, COSV55898229; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ANKRD2 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as rs1197437031, COSV53968341; called by muse, mutect2, varscan2
- COL7A1 | c.1342T>C p.W448R | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60399078; called by muse, mutect2, varscan2
- CXorf65 | c.332T>C p.I111T | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52149529; called by muse, mutect2, varscan2
- FMN2 | c.4251G>C p.K1417N | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV60440597; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); catalogued as rs200318618, COSV58550443; called by muse, mutect2
- GBP6 | c.576C>A p.H192Q | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs952788294, COSV65012107; called by muse, mutect2, varscan2
- KCNB1 | c.2389T>G p.F797V | Missense Mutation (SNP) | VAF 26/360 reads (7%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.006); catalogued as COSV100870399, COSV65569558; called by muse, mutect2
- PAX8 | c.113C>A p.A38D | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99639203; called by muse, mutect2
- PDZRN4 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs755317185, COSV68414139; called by muse, mutect2
- SPRED2 | c.589-1G>T p.X197_splice | Splice Site (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100710104, COSV100710203; called by muse, mutect2
- SYNE1 | c.3529A>G p.R1177G (on ENST00000367255 / NM_182961.4; = p.R1184G on NM_033071.3) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV99555656; called by muse, mutect2
- VPS4B | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.06); catalogued as rs142699030, COSV53070185; called by muse, mutect2, varscan2
- CEP128 | c.2567dup p.P857Sfs*2 | Frame Shift Ins (INS) | VAF 22/117 reads (19%) | called by mutect2, pindel, varscan2
- RBM15 | c.1249_1255del p.G417Sfs*6 | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | called by mutect2, pindel, varscan2
- IARS2 | c.357C>T p.N119= | Silent (SNP) | VAF 26/157 reads (17%) | catalogued as rs778652260, COSV56961993; called by muse, mutect2, varscan2
- IMPG1 | c.264G>A p.Q88= | Silent (SNP) | VAF 10/148 reads (7%) | catalogued as COSV100886155; called by muse, mutect2
- LRRK1 | c.2145G>A p.T715= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs772724015, COSV52613595, COSV52621144; called by muse, mutect2, varscan2
- PTPN23 | c.2166C>T p.A722= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV55546379; called by muse, mutect2, varscan2
- DIO2 | c.223-2988_223-2984del | Intron (DEL) | VAF 55/210 reads (26%) | catalogued as COSV70445786; called by mutect2, pindel, varscan2
- DPH6 | c.312+16081C>T | Intron (SNP) | VAF 15/62 reads (24%) | catalogued as rs757381366, COSV56615377, COSV56617044; called by muse, mutect2, varscan2
